Surgical pathology report (de-identified scan), TCGA case TCGA-60-2722, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Roswell Park, specimen TCGA-60-2722-01A (Primary Tumor).

[page 1 of 4]
SURGICAL PATHOLOGY REPORT

SPECIMEN(S): A. 4R RIGHT DISTAL PARATRACHEAL
B. 4L LEFT DISTAL PARATRACHEAL
C. LEVEL 7 SUBCARINAL
D. PLEURAL NODULES
E. RIGHT LUNG
F. NEW ADDITIONAL BRONCHIAL MARGIN
G. EXTRA MARGIN CARTILAGE
H. LEVEL 10 (HILAR) LYMPH NODE
I. LEVEL 7 LYMPH NODES
J. LEVEL 8 LYMPH NODE

PRE-OPERATIVE DIAGNOSIS:

Right lung mass.

INTRAOPERATIVE CONSULTATION:

FSA: Negative for carcinoma called to [REDACTED]
FSB: Negative for carcinoma called to [REDACTED]
FSC: Negative for carcinoma called to [REDACTED]
FSD: Negative for carcinoma, pleural [REDACTED]
FSE: Positive for carcinoma called to [REDACTED]
FSF: New additional brochial margin- Negative for tumor called to [REDACTED] y Dr.

FSG: Margin free of tumor called to [REDACTED]

[page 2 of 4]
GROSS DESCRIPTION:

A. 4 R RIGHT DISTAL PARATRACHEAL:

Received fresh for frozen section is a tan-pink lymph node 1.0 x 1.0 x 0.5cm. The specimen is bisected, touch preps are taken the specimen is submitted in toto for frozen section in FSA1.

B. 4L LEFT DISTAL PARATRACHEAL:

Received fresh for frozen section is a tan-pink lymph node 0.8 x 0.5 x 0.5cm. The specimen is bisected, touch preps are taken and the specimen is submitted in toto for frozen section in FSB1.

C. 7 SUBCARINAL:

Received fresh for frozen section is are two tan-pink soft tissue fragments 0.7 x 0.5 x 0.5cm and 0.6 x 0.6 x 0.5cm. The specimen is bisected, 2 touch preps are taken and the specimen is submitted in toto for frozen section in FSC.

D. PLEURAL NODULES:

Received fresh for frozen section are two tan white firm nodules 0.8 x 0.5 x 0.4cm and 0.5 x 0.4 x 0.3cm. The specimen is submitted in toto for frozen section is FSD1.

E. RIGHT LUNG BRONCHIAL MARGIN

Received fresh is a 695-g pneumonectomy specimen measuring 23.5 x 15.8 x 3.2 cm. The lateral pleura has an area of discoloration measuring up to 2.7 cm. The apex has an area of discoloration measuring 3 cm. Extending from the bronchus is a tan mass. Shave section is taken of the bronchia margin and the pleura is inked blue. Specimen is sectioned and there is a firm well-circumscribed tan mass measuring 3.7 x 2.8 x 2.8 cm. involving the bronchus and adjacent vessels. Areas of calcification and necrosis are observed. Grossly it does not appear to involve the pleura. The remainder of the parenchyma has a mmottled black and red coloration. A yellow-tan purulent material is exuded from the bronchioles. Several firm enlarged anthracotic lymph nodes are identified. Tissue is submitted for procurement including CALEB 140202, NCG 37304, and Study 112376. Representative sections are submitted as follows:

FSE1: frozen shaved section of bronchial margin

E2-E4: complete section including bronchi, lymph nodes, and parenchyma

E5-E8: sections of mass

E9: pleural areas of discoloration

E10: normal appearing parenchyma

E11-E14: lymph nodes

F. NEW ADDITIONAL BRONCHIAL MARGIN MEMBRANOUS

Received fresh is a bronchial margin with attached suture measuring 4.2 x 1.5 x 0.4 cm. The portion designated by the suture is shaved and submitted for frozen section in cassette FSF1.

G. EXTRA MARGIN CARTILAGE

Received fresh is a piece of cartilage with attached suture measuring 4.2 x 0.5 x 0.4 cm. The specimen is bisected longitudinally and section submitted entirely as follows:

G1: frozen section of cartilage

G2: remainder of cartilage

H. LEVEL 10 HILAR LYMPH NODE

Received in formalin is a firm anthracotic lymph node measuring 0.9 x 0.9 x 0.5 cm. Bisected, it has a uniform black cut surface. Submitted entirely in cassette H1.

I. LEVEL 7 LYMPH NODE

[page 3 of 4]
Received in formalin are two pieces of variegated black-tan-pink soft tissue, in aggregate measuring 2.4 x 2.4 x 0.9 cm. Specimen is bisected and multiple possible lymph nodes are identified. Specimen submitted entirely in cassettes I1-I2.

J. LEVEL 8 LYMPH NODE

Received in formalin is a nodular piece of variegated black-pink-tan soft tissue measuring 3 x 1.9 x 1.1 cm. Specimen is sectioned and one distinct lymph node is identified. Specimen submitted entirely in cassettes J1-J2.

DIAGNOSIS:

- A. 4 RIGHT DISTAL PARATRACHEAL LYMPH NODES:
- ONE LYMPH NODE – NEGATIVE FOR TUMOR.
- B. 4 LEFT DISTAL PARATRACHEAL LYMPH NODES;
- ONE LYMPH NODE WITH ANTHRACOSIS – NEGATIVE FOR TUMOR (0/1).
- C. LEVEL 7 SUBCARINAL LYMPH NODE:
- ONE LYMPH NODE – NEGATIVE FOR TUMOR (0/1).
- D. PLEURAL NODULES:
- FIBROUS HYALINIZED PLAQUE – NEGATIVE FOR TUMOR.
- E. RIGHT LUNG, PNEUMONECTOMY SPECIMEN:
- EXOPHYTIC INVASIVE MODERATE TO POORLY DIFFERENTIATED SQUAMOUS CELL CARCINOMA WITH AREAS OF NECROSIS OF RIGHT LUNG WITH METASTASIS TO ONE OUT OF TEN PERIBRONCHIAL LYMPH NODES (1/10).
- SIZE OF TUMOR – 3.7 x 2.8 x 2.8 CM.
- CONGESTION, ATELECTATIC CHANGE AND INTERSTITIAL FIBROSIS
(tumor at bronchial margin)
- F. NEW ADDITIONAL BRONCHIAL MARGINS:
- NEGATIVE FOR TUMOR.
- ONE LYMPH NODE – NEGATIVE FOR TUMOR (0/1).
- G. EXTRA MARGIN CARTILAGE:
- BRONCHIAL MUCOSA WITH CARTILAGE – NEGATIVE FOR TUMOR.
- H. LEVEL 10 (HILAR) LYMPH NODE:
- TWO LYMPH NODES WITH ANTHRACOSIS – NEGATIVE FOR TUMOR (0/2).
- I. LEVEL 7 LYMPH NODES:
- FIVE LYMPH NODES – NEGATIVE FOR TUMOR (0/5).
- J. LEVEL 8 LYMPH NODES:
- THREE LYMPH NODES – NEGATIVE FOR TUMOR (0/3).
-

[page 4 of 4]
Specimens Involved

Specimens: A: 4R RIGHT DISTAL PARATRACHEAL
B: 4L LEFT DISTAL PARATRACHEAL
C: LEVEL 7 SUBCARINAL
D: PLEURAL NODULES
E: RIGHT LUNG
F: NEW ADDITIONAL BRONCHIAL MARGIN
G: EXTRA MARGIN CARTILAGE
H: LEVEL 10 (HILAR) LYMPH NODE
I: LEVEL 7 LYMPH NODES
J: LEVEL 8 LYMPH NODE

Surgical Procedure: Pneumonectomy
Laterality: Right
Tumor Site: Upper lobe
Tumor Location: Central
Tumor Size: Greatest diameter: 3.7cm
Additional dimensions: 2.8cm x 2.8cm

WHO CLASSIFICATION

Squamous cell carcinoma
Histologic Grade: G2: Moderately differentiated
Angiolymphatic Invasion: Present
Cannot be determined
Bronchial Margins: Bronchial margins uninvolved
Comment: additional bronchial margins (#F,#G)-negative for tumor
Visceral Pleural Involvement: Absent
Satellite Tumor(s): Absent
Lymph Node Involvement: N1: Ipsilateral Hilar and/or Peribronchial (levels 10-14)
Positive 1 / 13
N2: Ipsilateral Mediastinal and/or Subcarinal (Levels 1-9)
Negative 0 / 10
N3: Contralateral Mediastinal/Hilar, Scalene or Supraclavicular
Negative 0 / 1
Non-Neoplastic Lung: Emphysematous changes
Congestion, interstitial fibrosis
Additional Pathologic Findings: Inflammation
Type: tumor necrosis
Pathological Staging (pTNM): pT 2 N 1 M X

Note: In specimen #E the tumor extends to bronchial margin, however additional submitted margins in specimen #F and #G shows no identifiable residual tumor.

Source: NCI Genomic Data Commons file c3dabc73-c322-4e9b-afce-3d83f9c5fb1d (TCGA-60-2722.1695C98E-F870-4A29-8987-ACB46860B525.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).